CCDI case PBCIEH — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Other and ill-defined digestive organs.
https://portal.gdc.cancer.gov/cases/7032b32b-b5f0-4ffe-bc52-2364ad667b1e

Demographics
Sex at birth: male; Race: black or african american.

Diagnoses (1)
1. Clear cell sarcoma of kidney: ICD-O-3 morphology code: 8964/3; Tissue or organ of origin: Kidney, NOS; Age at diagnosis: 1.5 years (554 days).

Biospecimens (3 samples)
- Samples 0DSMWR, 0DSMY2 (2 with the same recorded description): Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DSMYF: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
